Somatic mutation profile of tumor specimen TCGA-B4-5834-01A (aliquot TCGA-B4-5834-01A-11D-1669-08) from TCGA case TCGA-B4-5834, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 59.4 years (21,713 days).
Specimen TCGA-B4-5834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efb8a28d-f301-4d66-9ddd-5ff303cf1569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5834-10A (Blood Derived Normal), aliquot TCGA-B4-5834-10A-02D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49c34228-9cd6-45cf-b94f-2b3dee925d74

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Splice Site 2, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.8581A>C p.T2861P | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55085581; called by muse, mutect2, varscan2
- CEP170 | c.2501T>C p.V834A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100316761; called by mutect2, varscan2
- CTDP1 | c.2090C>G p.A697G | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV50009863; called by muse, mutect2, varscan2
- DDR2 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV63373891; called by muse, mutect2, varscan2
- DDX55 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1202085925, COSV53017929; called by muse, mutect2, varscan2
- DMAP1 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV60001900; called by muse, mutect2, varscan2
- IGSF10 | c.1336A>T p.S446C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs895015948, COSV56792839; called by muse, mutect2, varscan2
- ITPRID1 | c.1505T>C p.M502T | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs967259475, COSV60084191; called by muse, mutect2, varscan2
- ITSN1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV66086757; called by muse, mutect2, varscan2
- KCNJ1 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60663169; called by muse, mutect2, varscan2
- KNSTRN | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51112943; called by muse, mutect2, varscan2
- LNPK | c.317-2A>G p.X106_splice | Splice Site (SNP) | VAF 3/17 reads (18%) | catalogued as COSV55826748; called by muse, mutect2
- LRRC2 | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV56129210; called by muse, mutect2, varscan2
- MOAP1 | c.287dup p.D97* | Frame Shift Ins (INS) | VAF 40/176 reads (23%) | catalogued as rs1277979769; called by mutect2, pindel, varscan2
- MYH8 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67973753; called by muse, mutect2, varscan2
- NDOR1 | c.1370G>A p.G457E (on ENST00000371521 / NM_001144026.3; = p.G450E on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329593339, COSV61290273; called by muse, mutect2
- OR8B3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV63542306; called by muse, mutect2
- RFX1 | c.879C>G p.S293R | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV54334046; called by muse, mutect2, varscan2
- SLC1A5 | c.1496T>A p.I499K | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV69467683; called by muse, mutect2, varscan2
- SNX29 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV60071879; called by muse, mutect2, varscan2
- UTRN | c.5839A>T p.R1947* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV62349696; called by muse, mutect2, varscan2
- DHRS7C | c.570_574+3del p.X190_splice (on ENST00000330255 / NM_001220493.2; = p.X189_splice on NM_001105571.3) | Splice Site (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel
- EFCAB3 | c.783_786del p.M261Ifs*3 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- NFRKB | c.3265_3277delinsGC p.R1089Afs*139 (on ENST00000446488 / NM_001143835.2; = p.R1114Afs*139 on NM_006165.3) | Frame Shift Del (DEL) | VAF 27/158 reads (17%) | called by pindel, varscan2*
- ATP1A1 | c.1821A>T p.R607= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV55194706; called by muse, mutect2, varscan2
- FOXD4 | c.765T>C p.P255= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV58703568; called by muse, mutect2, varscan2
- HOOK2 | c.750G>A p.E250= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1161027691, COSV53404409; called by muse, mutect2, varscan2
- PMS2 | c.468A>T p.T156= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as rs1364918195, COSV56224724; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC39A7 | c.1065C>T p.V355= | Silent (SNP) | VAF 71/297 reads (24%) | catalogued as COSV63003017; called by muse, mutect2, varscan2
- SLC41A1 | c.717C>T p.V239= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV65651743; called by muse, mutect2, varscan2
- SUGP2 | c.1989C>T p.Y663= | Silent (SNP) | VAF 33/246 reads (13%) | catalogued as rs761612421, COSV58266336; called by muse, mutect2, varscan2
- SYNE3 | c.1659T>C p.F553= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV62083222; called by muse, mutect2, varscan2
- TOM1L1 | c.1230A>G p.Q410= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV61949790; called by muse, mutect2, varscan2
- YARS1 | c.846A>G p.K282= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs1358837336, COSV65115528; called by muse, mutect2, varscan2
- PAFAH2 | c.*1G>T | 3'UTR (SNP) | VAF 68/235 reads (29%) | catalogued as COSV100959230; called by muse, mutect2, varscan2
